Somatic mutation profile of tumor specimen BLGSP-71-08-00056-01A (aliquot BLGSP-71-08-00056-01A-01D-A671-33) from CGCI case BLGSP-71-08-00056, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS.
Specimen BLGSP-71-08-00056-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Maxilla; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7f658f5-baf7-47a6-9a40-6f60bb702ac4.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-08-00056-10A (Blood Derived Normal), aliquot BLGSP-71-08-00056-10A-01D-A671-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/404bbb87-90c6-4b90-a7a6-d8d79e44eb7b

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, 5'UTR 2, 5'Flank 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ID3 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV101000770; called by muse, varscan2
- ID3 | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65800754, COSV65801030, COSV65801279; called by muse, varscan2
- BCL6 | c.1675G>C p.G559R | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD8 | c.3281G>A p.C1094Y (on ENST00000646647 / NM_001170629.2; = p.C815Y on NM_020920.4) | Missense Mutation (SNP) | VAF 146/315 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SON | c.6518A>C p.K2173T | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ID3 | c.165A>T p.V55= | Silent (SNP) | VAF 20/30 reads (67%) | called by muse, varscan2
- UNC13C | c.2814A>G p.L938= | Silent (SNP) | VAF 254/528 reads (48%) | called by muse, mutect2, varscan2
- MYC | c.-199G>A | 5'UTR (SNP) | VAF 50/115 reads (43%) | catalogued as COSV104388104, COSV104388105, COSV52374047; called by muse, varscan2
- MYC | c.-19C>T | 5'UTR (SNP) | VAF 62/153 reads (41%) | catalogued as COSV52367078, COSV52370462; called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331807 T>C | 5'Flank (SNP) | VAF 73/163 reads (45%) | called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58332055 C>T | 5'Flank (SNP) | VAF 134/286 reads (47%) | called by muse, varscan2
